CCDI case PBBUDW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/c1d848e0-e440-45f3-be39-37a426b9884b

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Tumor cells, malignant: ICD-O-3 morphology code: 8001/3; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 4.6 years (1,689 days).

Biospecimens (3 samples)
- Sample 0DI5EC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI5ER: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI5F7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
